CGCI case HTMCP-02-01-01256 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c376b633-846c-4c65-b39d-94c3526c772e

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC clinical stage: Stage IV; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days.
   Pathology details: Lymph nodes positive: 3; Lymph nodes tested: 18.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day 0: Weight: 66 kg; Height: 166 cm; BMI: 24; CD4 count: 1624; Haart treatment indicator: No; HIV viral load: 159.
- Day 0: Comorbidities: Hepatitis C Infection.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 44.

Biospecimens (3 samples)
- Sample HTMCP-02-01-01256-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-01-01256-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-01-01256-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Adenocarcinoma, Not Otherwise Specified; Tobacco smoking age started: 9; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: Yes.
- New tumor event: New tumor event site: Lung.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Lower lobe.
- History of disease: Year of HIV diagnosis: 2005; Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: No.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Other method, specify:; Other pos node location: peribronchial.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-01-01256-01A-01E-17519:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-01-01256-11A-01E-17519:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-01-01256-01A-01S-17519:
- % tumour top: 70
- % tumour bottom: 70
